CCDI case PBBYAT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Meningiomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/04a0e081-fe5f-4be3-91d5-0425e63ef61f

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Clear cell meningioma: ICD-O-3 morphology code: 9538/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.8 years (7,216 days).

Biospecimens (2 samples)
- Sample 0DLIF5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLIFL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
